Somatic mutation profile of tumor specimen C3L-02958-01 (aliquot CPT0196990006) from CPTAC case C3L-02958, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA1; Tumor grade: G1; Age at diagnosis: 74.3 years (27,124 days).
Specimen C3L-02958-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f4c317d-a18a-4772-987b-75f768f7765d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02958-31 (Blood Derived Normal), aliquot CPT0197810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05e3c3ce-13ab-4a21-9489-af8e2a71ec74

The open-access MAF lists 54 somatic variants for this specimen: 44 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, Splice Site 6, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028+1G>C p.X1010_splice | Splice Site (SNP) | VAF 66/328 reads (20%) | hotspot (GDC flag); catalogued as COSV59256499, COSV59256681, COSV59259384, COSV59260405; called by muse, mutect2, varscan2
- MET | c.3028+2T>A p.X1010_splice | Splice Site (SNP) | VAF 64/324 reads (20%) | hotspot (GDC flag); catalogued as COSV100577355, COSV59257966, COSV59268376, COSV59269013; called by muse, mutect2, varscan2
- SYN1 | c.635G>T p.S212I | Missense Mutation (SNP) | VAF 117/292 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1556860638; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CCDC168 | c.5497C>A p.H1833N | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1158699618; called by muse, mutect2
- CHRM3 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55103986; called by muse, mutect2
- DMRTC2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs879954211; called by muse, mutect2
- ENPEP | c.316G>T p.V106L | Missense Mutation (SNP) | VAF 37/622 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54455144; called by muse, mutect2
- IGSF10 | c.2207G>C p.R736P | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV56784526; called by muse, mutect2
- ITPK1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 46/529 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as rs1239724258; called by muse, mutect2
- MAK | c.358+2T>C p.X120_splice | Splice Site (SNP) | VAF 44/288 reads (15%) | catalogued as rs1446287566; called by muse, mutect2, varscan2
- NPAP1 | c.3188G>A p.G1063D | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT tolerated, low confidence (0.75); PolyPhen possibly damaging (0.685); catalogued as COSV100274785; called by muse, mutect2
- NR2F2 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 37/395 reads (9%) | catalogued as COSV67683567; called by muse, mutect2
- OR10A2 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs750033071, COSV100225020, COSV56300107; called by muse, mutect2
- PDZRN3 | c.2837G>A p.R946H | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV55214954; called by muse, mutect2
- SAMHD1 | c.1084A>T p.M362L | Missense Mutation (SNP) | VAF 20/387 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.888); catalogued as COSV99484359; called by muse, mutect2
- SNX27 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as rs759653250; called by muse, mutect2, varscan2
- SPESP1 | c.779A>T p.H260L | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV52993257; called by muse, mutect2
- ANTXR2 | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 15/461 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOBR | c.740G>C p.G247A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2
- C1orf167 | c.4139dup p.V1382Sfs*4 | Frame Shift Ins (INS) | VAF 36/218 reads (17%) | called by mutect2, pindel, varscan2
- CADPS | c.3304G>A p.D1102N | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- CAMKK1 | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- CLK3 | c.1051_1053del p.N351del (on ENST00000395066 / NM_001130028.1; = p.N203del on NM_003992.4) | In Frame Del (DEL) | VAF 18/147 reads (12%) | called by mutect2, pindel, varscan2
- COG6 | c.1455_1465del p.T486Qfs*7 | Frame Shift Del (DEL) | VAF 44/268 reads (16%) | called by mutect2, pindel, varscan2
- COL14A1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- DENND4B | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- FAM171A1 | c.592C>A p.H198N | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2
- GUCY1A2 | c.1111G>T p.V371F | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- INPPL1 | c.1297A>G p.M433V | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- IRAK3 | c.1214A>G p.K405R | Missense Mutation (SNP) | VAF 61/1228 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.096); called by muse, mutect2
- JMJD1C | c.2148T>A p.D716E | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- LRRC6 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- MET | c.3335del p.L1112* | Frame Shift Del (DEL) | VAF 57/395 reads (14%) | called by mutect2, pindel, varscan2
- METTL16 | c.410T>C p.M137T | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- OR8U1 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- PRG4 | c.4017del p.S1340Vfs*75 | Frame Shift Del (DEL) | VAF 33/262 reads (13%) | called by mutect2, pindel, varscan2
- R3HDM2 | c.208-2A>G p.X70_splice | Splice Site (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- RANBP3 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.22); called by muse, mutect2
- RBM10 | c.1575+2T>A p.X525_splice | Splice Site (SNP) | VAF 31/227 reads (14%) | called by muse, mutect2, varscan2
- SAMD4A | c.580C>G p.R194G | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); called by muse, mutect2
- SOX3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.079); called by muse, mutect2
- SPEF2 | c.3731C>A p.S1244Y | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- STIP1 | c.504-3_518del p.X168_splice | Splice Site (DEL) | VAF 15/175 reads (9%) | called by mutect2, pindel
- ZFHX3 | c.5648A>C p.K1883T | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- CAPN15 | c.1546C>T p.L516= | Silent (SNP) | VAF 35/557 reads (6%) | catalogued as COSV54834946; called by muse, mutect2
- CTDSPL2 | c.942A>G p.P314= | Silent (SNP) | VAF 31/163 reads (19%) | called by muse, mutect2, varscan2
- MAB21L1 | c.402G>C p.T134= | Silent (SNP) | VAF 40/242 reads (17%) | called by muse, mutect2, varscan2
- NKX2-1 | c.840C>T p.A280= | Silent (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2
- NPBWR2 | c.273C>T p.D91= | Silent (SNP) | VAF 29/343 reads (8%) | catalogued as rs757799530; called by muse, mutect2
- ZNF573 | c.1485G>A p.E495= (on ENST00000536220 / NM_001172692.1; = p.E437= on NM_152360.3) | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- ZNF747 | c.399T>G p.S133= | Silent (SNP) | VAF 23/270 reads (9%) | called by muse, mutect2
- ACADVL | c.753-12A>G | Intron (SNP) | VAF 61/416 reads (15%) | called by muse, mutect2, varscan2
- PRPH | c.-40G>A | 5'UTR (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- SERINC2 | c.39+759G>A | Intron (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2
